CCDI case PBCKUD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/f24f93ce-071f-40b4-ad93-63854b57bdd0

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Spindle cell rhabdomyosarcoma: ICD-O-3 morphology code: 8912/3; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 24.9 years (9,085 days).

Biospecimens (2 samples)
- Samples 0DUCRM, 0DUCRY (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
